Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01G, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01G-01A (Primary Tumor).

TCGA #: _____ Sample ID #: _____

Diagnosis:

Right hemicolectomy preparation with tumor-free resection margins and displaying an ulcerated, moderately differentiated adenocarcinoma of the cecum, with some sections showing more relatively marked production of mucus, with infiltration of the perimuscular fatty tissue and without local lymph node metastases (G2, pT3 L0 V0 R0 pN0 0/22).

1CD-0-3

adenocarcinoma, mucinous, NOS 8480/3

Site: Cecum C18.0 for 3/30/11

Referrer Initials		

5/16/11

KMI

Source: NCI Genomic Data Commons file fe9f1768-fcd9-41c1-aec0-415dfd005054 (TCGA-AA-A01G.4E27D129-1AC8-4382-B77B-9F8545EFEBE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).